Surgical pathology report (de-identified scan), TCGA case TCGA-A6-5665, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-5665-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Right colon

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right colon cancer

GROSS DESCRIPTION

Received fresh, labeled "right colon" is a previously unopened, 23 cm. segment of proximal right colon with attached 8 cm. of distal ileum surfaced by smooth to scabrous tan-pink serosa with a moderate amount of attached mesocolon, mesentery and unremarkable omentum. On opening, there is a well-circumscribed, 6.5 x 4.4 cm. centrally necrotic white pink-red tumor mass 3 cm. distal to the ileocecal valve. On sectioning, the lesion has a maximal thickness of 1.2 cm., grossly extending into the muscularis to within 0.4 cm. of the inked free radial serosal surface. Two additional mucosal polyps averaging 0.5 cm. are present within the colon, 7.5 cm. proximal and 9 cm. distal to the tumor. The remaining colonic mucosa is unremarkable, glistening tan-pink with regular folds and the wall averages 0.4 cm in thickness. The ileal mucosa is unremarkable glistening tan pink

with

regular folds and the wall averages 0.4 cm. in thickness. The appendix is not present. A portion of tumor and a portion of

normal

mucosa are submitted for tissue procurement as requested. Several soft tan-pink tissues in keeping with lymph nodes measuring up to 0.9 cm. in greatest dimension are recovered from the attached mesocolon and mesentery. Representative sections are submitted in 12 blocks as labeled. RS-12.

BLOCK SUMMARY: 1 - Proximal and distal margins; 2, 3 - tumor full thickness to inked free radial serosal surface; 4 - central tumor;

5

- tumor to normal mucosa; 6 - colonic polyp; 7 - ICV; 8 - random colon and ileum; 9-11 - six ole lymph nodes per cassette; 12 - five whole lymph nodes.

MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma

Histologic grade: Moderately to poorly differentiated

Primary tumor (pT): Tumor invades through the muscularis propria focally into the pericolonic fat (pT3)

Proximal margin: Negative for tumor

Distal margin: Negative for tumor

Circumferential (radial) margin: Negative for tumor

[page 2 of 2]
Distance of tumor from closest margin: 11 cm. from proximal margin (ileum)

Vascular invasion: Lymphatic space invasion is identified, best seen in slide 4, no venous or arterial space invasion is identified

Regional lymph nodes (pN): 25 lymph nodes are dissected from the specimen, they were all negative for metastatic tumor (pN0)

Non-lymph node pericolic tumor: Not identified

Distant metastasis (pM): Cannot evaluate pMx

Other findings: Approximately 30% of the tumor has mucinous differentiation and is seen in blocks 4 and 5. The most deeply invasive portion of the tumor is not mucinous and is poorly differentiated and seen in blocks 2 and 3. The ileocecal valve is unremarkable. No appendix is identified. An additional tubular adenoma is noted in block 6.

5x1, 3260F

DIAGNOSIS

A. Colon, right, segmental resection:

Invasive adenocarcinoma, moderately to poorly differentiated, invasive into pericolic fat (pT3)

Lymphovascular space invasion present.

25 lymph nodes are negative for metastatic tumor (pN0).

Additional adenomatous polyp.

--- End Of Report ---

Source: NCI Genomic Data Commons file 866e0c45-9c3f-43f8-818c-947f3e250206 (TCGA-A6-5665.814C8056-1298-4941-9FDE-C660DAE23C0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).